Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3CL, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3CL-01A (Primary Tumor).

Diagnosis Discrepancy	Emended site	

10/15/11

History Case Pathology Report

Department of Pathology,
Tel: Fax:

DOB:
Physician

Sex: F

Received:

Pathologist:

Accession:

Case type: Surgical History

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to the section "SPECIMEN" may have been added. ****

DIAGNOSIS

- (A) THYROID ISTHMUS, RESECTION:
PAPILLARY CARCINOMA OF THYROID. (SEE COMMENT)
No lymphatic/vascular invasion or extrathyroidal extension identified.
Resection margins free of tumor.
- (B) TISSUE OVERLYING CRICOID, BIOPSY:
Cartilage and skeletal muscle, no tumor present.
- (C) SOFT TISSUE, LEFT THIGH, EXCISION:
Atypical lipoma (5550 gms) with areas of necrosis.

COMMENT

The papillary carcinoma is 3.0 cm and is composed of a mixture of papillary and follicular variant pattern. The tumor is encapsulated and contains calcifications.

SPECIMEN

- (A) THYROID ISTHMUS, RESECTION:
(B) TISSUE OVERLYING CRICOID, BIOPSY:
(C) SOFT TISSUE, LEFT THIGH, EXCISION:

SNOMED CODES

T-B6000, M-80503

ICIS 0-3
Path: carcinoma, papillary and follicular 8340/3

Site: Thyroid, NOS C73.9

hw
10/15/11

CQCF: carcinoma, papillary, thyroid 8260/3
(follicular <99%)

Source: NCI Genomic Data Commons file 8c14dfaf-4f36-4e3b-aef3-58e3a2616fb2 (TCGA-EL-A3CL.321767E5-697C-4958-9766-F25745B3D1D5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).